Gene-level copy-number profile of tumor specimen TCGA-AA-3517-01A from TCGA case TCGA-AA-3517, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60.5 years (22,099 days).
Specimen TCGA-AA-3517-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.04e33010-cddb-4f24-9b92-18bb32d8f975.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3517-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3dd277af-f069-450d-91a9-31199d8bccb6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 15; copy number 2: 11,262; copy number 3: 11,871; copy number 4: 28,271; copy number 5: 3,094; copy number 6: 2,723; copy number 8: 9; copy number 9: 1,382; copy number 10: 13; copy number 11: 79; copy number 12: 971; copy number 13: 81; copy number 14: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3517-01A-01D-1549-01): tumor purity 0.79, ploidy 3.77, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,214,672, 15 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,549 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,318,861, 10 genes, copy number 10 (within-gene range 5–10): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr13:18,467,172–81,302,407, 971 genes, copy number 9 (broad region; genes not listed).
- chr13:83,996,173–114,337,626, 411 genes, copy number 9 (broad region; genes not listed).
- chr17:29,021,325–29,404,105, 11 genes, copy number 13 (within-gene range 4–13): AC024619.4, MYO18A, TIAF1, AC024619.3, AC005412.1, TWF1P1, CRYBA1, NUFIP2, RPL35AP35, AC068025.2, AC068025.1.
- chr17:32,142,454–32,253,374, 1 gene, copy number 11 (within-gene range 4–11): RHOT1.
- chr17:32,159,311–32,265,404, 4 genes, copy number 11–14: AC116407.4, AC116407.3, UBL5P2, AC026620.2.
- chr17:33,529,787–33,635,057, 4 genes, copy number 11: AA06, AC011824.3, AC011824.2, AC011824.1.
- chr17:34,980,512–35,089,319, 2 genes, copy number 10 (within-gene range 4–10): LIG3, RFFL.
- chr17:35,018,660–35,018,991, 1 gene, copy number 10: AC004223.4.
- chr17:37,686,431–38,257,192, 16 genes, copy number 11–12: HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA.
- chr17:39,687,914–39,864,312, 7 genes, copy number 14 (within-gene range 4–14): ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1.
- chr17:43,607,436–43,863,639, 10 genes, copy number 14: Metazoa_SRP, MEOX1, LINC02594, WHSC1L2P, SOST, DUSP3, CFAP97D1, AC003098.1, MPP3, CD300LG.
- chr17:44,557,484–44,752,264, 11 genes, copy number 11: FZD2, AC091152.3, SMCO4P1, LINC01180, MEIOC, CCDC43, AC091152.2, AC091152.4, DBF4B, RN7SL819P, AC091152.1.
- chr17:53,105,734–54,365,634, 9 genes, copy number 11 (within-gene range 4–11): MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1.
- chr17:60,392,429–60,562,161, 6 genes, copy number 12: C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1, AC011921.2.
- chr17:60,564,740–60,565,671, 1 gene, copy number 12: RPSAP66.
- chr17:62,808,500–63,611,184, 29 genes, copy number 12 (within-gene range 4–12): MARCHF10-DT, PRELID3BP3, AC005972.3, MIR633, TRMT112P3, AC005972.1, AC005972.2, TANC2, AC006270.2, AC006270.1, DNAJB6P8, AC015923.1, AC005828.2, AC005828.7, AC005828.1, AC005828.3, AC005828.6, AC005828.4, CYB561, AC005828.5, PPIAP55, ACE, AC113554.1, ACE3P, KCNH6, DCAF7, RNU6-288P, TACO1, AC046185.2.
- chr17:63,636,601–63,637,113, 1 gene, copy number 12: EEF1DP7.
- chr17:66,197,693–66,278,664, 4 genes, copy number 11: PSMD7P1, APOH, RNA5SP444, AC009452.1.
- chr17:66,364,029–66,416,854, 2 genes, copy number 11: RN7SL735P, PRKCA-AS1.
- chr17:67,377,281–67,697,261, 1 gene, copy number 13 (within-gene range 4–13): PITPNC1.
- chr17:67,471,489–67,996,469, 16 genes, copy number 13: MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58.
- chr17:75,667,251–76,154,650, 32 genes, copy number 11: SAP30BP, AC087749.2, AC087749.1, ITGB4, GALK1, H3-3B, MIR4738, UNK, AC087289.1, UNC13D, WBP2, TRIM47, AC087289.5, TRIM65, AC087289.2, MRPL38, AC087289.3, FBF1, ACOX1, AC087289.4, TEN1-CDK3, TEN1, CDK3, EVPL, SRP68, ZACN, GALR2, EXOC7, AC018665.1, MIR6868, FOXJ1, RNF157-AS1.
- chr17:76,831,684–76,969,156, 5 genes, copy number 14: AC016168.4, LINC00868, MGAT5B, AC016168.2, AC016168.1.
- chr17:78,971,238–79,049,788, 4 genes, copy number 12: LGALS3BP, CANT1, C1QTNF1-AS1, C1QTNF1.
- chr17:79,598,032–79,850,110, 10 genes, copy number 11: AC233701.1, MIR4739, LINC02078, ENPP7, CBX2, CBX8, AC100791.2, LINC01977, CBX4, AC100791.1.
- chr20:24,469,629–24,666,616, 1 gene, copy number 12 (within-gene range 2–12): SYNDIG1.
- chr20:24,679,547–64,313,132, 969 genes, copy number 12–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
